CPTAC case C3N-04273 — Oropharynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Oropharynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/701129b7-d95a-4fac-a9be-0d0da0642a81

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Dead; Days to death: 425 days (1.2 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Oropharynx, NOS; Site of resection or biopsy: Oropharynx, NOS; Age at diagnosis: 73.6 years (26,874 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 425 days (1.2 years); Progression or recurrence: no; Days to last follow up: 377 days (1.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm; Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 22; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 377 days (1.0 years); Disease response: Progressive Disease; Karnofsky performance status: 40; ECOG performance status: 5.
- Days to follow up: 377 days (1.0 years); Disease response: With Tumor; Karnofsky performance status: 40; ECOG performance status: 5.

Other clinical attributes
- Weight: 75 kg; Height: 172 cm; BMI: 25.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 38; Cigarettes per day: 20; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 2012; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 38.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04273-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 77 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04273-21: Section location: Oropharynx; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3N-04273-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 112 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04273-23: Section location: Oropharynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-04273-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
